Gene-level copy-number profile of tumor specimen TCGA-3X-AAVB-01A from TCGA case TCGA-3X-AAVB, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IVB; Tumor grade: G1; Age at diagnosis: 70.7 years (25,819 days).
Specimen TCGA-3X-AAVB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CHOL.fcf718b5-834b-4624-9980-105f7ebc9f1b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3X-AAVB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/262a45be-6c1e-417f-920f-b65f19f1bda8

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 3: 13,468; copy number 4: 17,421; copy number 5: 3,225; copy number 6: 25,026; copy number 7: 122; copy number 8: 103; copy number 9: 130; copy number 16: 204; copy number 24: 101.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3X-AAVB-01A-31D-A416-01): tumor purity 0.34, ploidy 3.23, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–4): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,009,305, 2 genes: AL449423.1, CDKN2B.
- chr9:130,044,713–130,638,352, 9 genes (within-gene range 0–4): AL136141.1, GPR107, Y_RNA, GPRACR, NCS1, HMCN2, RN7SL665P, ASS1, FUBP3.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 305 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:91,264,433–102,434,780, 305 genes, copy number 16–24 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
